MMRF case MMRF_1361 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8bee5c58-aaa5-4456-a5f8-6808b1276911

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 67 years; Vital status: Dead; Days to death: 207 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.4 years (24,610 days); ISS stage: III; Days to last known disease status: 207 days; Days to last follow up: 207 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 47 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 68 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 22 days; Days to treatment end: 68 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 47 days; Days to treatment end: 68 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 68 days; Days to treatment end: 154 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 68 days; Days to treatment end: 160 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 68 days; Days to treatment end: 138 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 117 days; Days to treatment end: 153 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 207.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0: M Protein 5.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.809 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1150 mg/dL; Immunoglobulin G 60.7 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.04 g/L; Beta 2 Microglobulin 26.2 µg/mL; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 5.08 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 2.56 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 424 µmol/L; Blood Urea Nitrogen 21.1 mmol/L; Calcium 2.25 mmol/L; Albumin 32 g/L; Total Protein 11.1 g/dL; Glucose 5.61 mmol/L; C-Reactive Protein 1.8 mg/dL.
- Day 103 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 50.4 mg/dL; Immunoglobulin G 7.41 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.03 g/L; Lactate Dehydrogenase 3.38 µkat/L; Hemoglobin 4.77 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.11 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 239 µmol/L; Blood Urea Nitrogen 13.9 mmol/L; Calcium 2.15 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 7.54 mmol/L.
- Day 180 (ECOG 1): M Protein 0.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.668 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 69.4 mg/dL; Immunoglobulin G 8.8 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 5.6 µg/mL; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 4.34 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 194 µmol/L; Blood Urea Nitrogen 17.5 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 6 g/dL; Glucose 12.3 mmol/L.

Other clinical attributes
- Day 0: Weight: 74 kg; Height: 170 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Colorectal Cancer.

Biospecimens (3 samples)
- Sample MMRF_1361_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1361_2_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
- Sample MMRF_1361_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 180 days.
